Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A75M, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A75M-01A (Primary Tumor).

Final Diagnosis:

Brain, right parietal #1 & #2, resection: Low grade diffuse astrocytoma (WHO grade II).

Immunohistochemical stains performed on paraffin sections of the right parietal lesion (block B1) reveal the neoplastic cells are positive for GFAP and reveal a high level of p53 labeling. The Ki-67 proliferation index is low overall with focal increase. IDH-1 (R132H) is negative. These findings are consistent with the above diagnosis.

Seen in consultation with

Pyrosequencing for IDH will be reported in an addendum.

Interpreted by:

Report electronically signed by

Transcribed by:

ADDENDA:

Result:

Positive for *IDH1* codon 132 c.394C>T p.Arg132Cys (R132C) mutation and negative for *IDH2* codon 172 mutation by PCR and pyrosequencing. All controls worked appropriately.

ALL EMBEDDED

continued next page Page 1 of 3

ICD-O-3
Astrocytoma, grade II
9400/3
Site B Brain, supratentorial (no)
C71.0
JW 8/12/13

Source: NCI Genomic Data Commons file 34248a96-6396-4185-aad8-38ae2d92631d (TCGA-DB-A75M.C19F2C06-B479-44A0-8BE2-A7DDD650D879.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).